Somatic mutation profile of tumor specimen TCGA-ZF-A9R9-01A (aliquot TCGA-ZF-A9R9-01A-11D-A38G-08) from TCGA case TCGA-ZF-A9R9, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 58.8 years (21,491 days).
Specimen TCGA-ZF-A9R9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bee7ef4-d919-4f9b-8e68-9a7e3ef349ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-A9R9-10A (Blood Derived Normal), aliquot TCGA-ZF-A9R9-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d22a0027-6d15-49bd-b9ae-4b870afdd507

The open-access MAF lists 214 somatic variants for this specimen: 157 protein-altering or splice-affecting, 52 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 134, Silent 52, Nonsense Mutation 16, Frame Shift Del 2, Splice Region 2, 5'Flank 1, 5'UTR 1, Frame Shift Ins 1, Intron 1, 3'Flank 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SGPL1 | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 15/113 reads (13%) | catalogued as rs746887949, COSV100940349; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC131160.1 | c.899T>G p.F300C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57701294; called by muse, mutect2, varscan2
- ACAT1 | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327844613, COSV56188352; called by muse, mutect2, varscan2
- ADRM1 | c.181T>C p.W61R | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53387285; called by muse, mutect2, varscan2
- AHNAK2 | c.10096G>A p.E3366K | Missense Mutation (SNP) | VAF 52/257 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1467273759, COSV60920991; called by muse, mutect2, varscan2
- ALKBH5 | c.838A>G p.I280V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV67687145; called by muse, mutect2, varscan2
- ALMS1 | c.5935G>T p.G1979W | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52514145; called by muse, mutect2, varscan2
- AMN1 | c.254G>C p.R85T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as COSV55672178; called by muse, mutect2, varscan2
- ANAPC5 | c.1560G>C p.M520I | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.164); catalogued as COSV55843707; called by muse, mutect2, varscan2
- ANKRD28 | c.2104G>A p.V702I | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as rs770719343, COSV67518985; called by muse, mutect2, varscan2
- ANKRD28 | c.696G>A p.M232I | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67518991; called by muse, mutect2, varscan2
- ANKRD50 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as rs1011161674, COSV72386347; called by muse, mutect2
- APC | c.2432C>T p.S811L | Missense Mutation (SNP) | VAF 43/60 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as CM010749, COSV57338557, COSV57358113; called by muse, mutect2, varscan2
- APC | c.3724C>T p.Q1242* | Nonsense Mutation (SNP) | VAF 18/22 reads (82%) | catalogued as rs1460397656, CM061638, COSV99965141; called by muse, varscan2
- APP | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV61000847; called by muse, mutect2, varscan2
- ARHGAP27 | c.1240C>G p.Q414E (on ENST00000428638 / NM_001282290.1; = p.Q73E on NM_199282.3) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV65358116; called by muse, mutect2, varscan2
- ARID1A | c.5734G>A p.D1912N | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.397); catalogued as COSV61381995; called by muse, mutect2, varscan2
- ARL8B | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 62/334 reads (19%) | catalogued as COSV56577041; called by muse, mutect2, varscan2
- ATAD2 | c.2165G>C p.R722T | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV54883321; called by muse, mutect2, varscan2
- ATAD2 | c.1885G>T p.E629* | Nonsense Mutation (SNP) | VAF 12/162 reads (7%) | catalogued as COSV99784539; called by muse, mutect2
- BATF3 | c.125G>C p.R42T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV54658753; called by muse, mutect2, varscan2
- BEND3 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs782415484, COSV64681394; called by muse, mutect2, varscan2
- BIRC6 | c.826C>G p.R276G | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.49); catalogued as COSV101428167, COSV70202285; called by muse, mutect2, varscan2
- BMP2K | c.2894G>C p.S965T | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.038); catalogued as COSV55008267, COSV55010559; called by muse, mutect2, varscan2
- BRD2 | c.404A>G p.Y135C | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66373863; called by muse, mutect2, varscan2
- C10orf90 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.648); catalogued as rs752212319, COSV52958568; called by muse, mutect2, varscan2
- C3orf62 | c.447G>A p.R149= | Splice Region (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99649252; called by muse, mutect2
- CAPN3 | c.1551G>C p.K517N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV58824182; called by muse, mutect2, varscan2
- CAPN3 | c.1552C>A p.Q518K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.199); catalogued as COSV58824209; called by muse, mutect2, varscan2
- CASZ1 | c.4147G>A p.E1383K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.63); catalogued as rs755943898, COSV59734366; called by muse, mutect2, varscan2
- CDH23 | c.2959G>T p.D987Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770665588, CM163803, COSV99820439, COSV99823663; called by muse, varscan2
- CELSR3 | c.7054C>T p.R2352* | Nonsense Mutation (SNP) | VAF 38/131 reads (29%) | catalogued as COSV50840836; called by muse, mutect2, varscan2
- CFAP47 | c.5426C>G p.S1809C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV100545262; called by muse, mutect2, varscan2
- CLASP1 | c.1655C>G p.S552* | Nonsense Mutation (SNP) | VAF 18/28 reads (64%) | catalogued as COSV99754360; called by muse, mutect2, varscan2
- COL16A1 | c.3857G>A p.R1286K | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as COSV54709691; called by muse, mutect2, varscan2
- CSPP1 | c.3721G>A p.E1241K (on ENST00000676605; = p.E1200K on NM_024790.6) | Missense Mutation (SNP) | VAF 121/161 reads (75%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.795); catalogued as rs201972175, COSV99139068; called by muse, mutect2, varscan2
- CUBN | c.1935A>T p.K645N | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.582); catalogued as COSV64720416; called by muse, mutect2, varscan2
- DCC | c.4062G>A p.M1354I | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.565); catalogued as COSV71434645; called by muse, mutect2, varscan2
- DCLRE1B | c.1513C>G p.L505V | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV65812794, COSV65813144; called by muse, mutect2, varscan2
- DDX23 | c.2280G>C p.K760N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV56399404; called by muse, varscan2
- DDX23 | c.2019G>C p.Q673H | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV56399417; called by muse, mutect2, varscan2
- DHX15 | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 25/47 reads (53%) | catalogued as COSV100391321; called by muse, mutect2, varscan2
- DIP2B | c.1719G>A p.A573= | Splice Region (SNP) | VAF 4/75 reads (5%) | catalogued as rs1310258816, COSV99998572; called by muse, mutect2
- DMXL2 | c.6626C>T p.S2209L | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.977); catalogued as rs1200664389, COSV51840842; called by muse, mutect2, varscan2
- DNMBP | c.4184C>T p.T1395I | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV60628551; called by muse, mutect2, varscan2
- DYNC2H1 | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.034); catalogued as COSV62099118; called by muse, mutect2, varscan2
- DZIP1L | c.1300T>C p.S434P | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV59522119; called by muse, mutect2, varscan2
- EIF2AK4 | c.4887A>C p.E1629D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as COSV51115757; called by muse, mutect2, varscan2
- EML1 | c.1495-1G>C p.X499_splice | Splice Site (SNP) | VAF 16/72 reads (22%) | catalogued as COSV51748218; called by muse, mutect2, varscan2
- EPC1 | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.195); catalogued as COSV53927520; called by muse, mutect2, varscan2
- ETS1 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs756820963, COSV67007756; called by muse, mutect2, varscan2
- FAH | c.851T>C p.L284P | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV55722353; called by muse, mutect2, varscan2
- FLI1 | c.963G>A p.W321* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as rs1466540970, COSV99857622; called by muse, mutect2, varscan2
- GALNT14 | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV61107542, COSV61107570; called by muse, mutect2, varscan2
- GAREM1 | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52512220; called by muse, mutect2, varscan2
- GEMIN2 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51627100; called by muse, mutect2, varscan2
- GLIS1 | c.568G>T p.V190L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100389851; called by muse, mutect2
- GOLGA4 | c.1116G>C p.Q372H | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62711904; called by muse, varscan2
- GPS1 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV57650206; called by muse, mutect2, varscan2
- H2AW | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.926); catalogued as COSV64209916; called by muse, mutect2, varscan2
- HECTD4 | c.6610A>G p.R2204G | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); catalogued as COSV66394920; called by muse, mutect2, varscan2
- HELZ | c.1638G>C p.Q546H | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV62379389; called by muse, mutect2, varscan2
- HFM1 | c.2611C>T p.P871S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.505); catalogued as COSV54031331; called by muse, mutect2, varscan2
- HORMAD1 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV59272050; called by muse, mutect2, varscan2
- ICAM1 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.196); catalogued as rs143008699, COSV99320913; called by muse, mutect2, varscan2
- IMPDH2 | c.451G>C p.G151R | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV58708313; called by muse, mutect2, varscan2
- INSIG1 | c.754T>A p.F252I | Missense Mutation (SNP) | VAF 105/246 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100452959; called by muse, varscan2
- IZUMO4 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.94); catalogued as rs369286997; called by muse, mutect2, varscan2
- JHY | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.536); catalogued as COSV57077203; called by muse, mutect2, varscan2
- KIF13A | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 42/106 reads (40%) | catalogued as COSV52459601, COSV99435531; called by muse, mutect2, varscan2
- KLF11 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 29/62 reads (47%) | catalogued as COSV100007713, COSV100007842; called by muse, mutect2, varscan2
- KLHL14 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.806); catalogued as COSV63833921; called by muse, mutect2, varscan2
- KREMEN2 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs754585683, COSV53556650; called by muse, mutect2, varscan2
- KRTAP1-1 | c.455C>A p.S152Y | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV60398688; called by muse, mutect2, varscan2
- LONRF1 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as rs374942182; called by muse, mutect2, varscan2
- MAGI1 | c.980C>G p.S327C | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1308159408, COSV58333861; called by muse, mutect2, varscan2
- MCM7 | c.1677G>C p.M559I | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as COSV57997381; called by muse, mutect2, varscan2
- MKNK1 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs1188316063, COSV57861977; called by muse, mutect2
- MRGPRX1 | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.796); catalogued as rs372814324; called by muse, mutect2, varscan2
- MRPL34 | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); catalogued as rs752741313, COSV53113065, COSV99395469; called by muse, varscan2
- MYO15A | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as rs1175247562, COSV52760118; called by muse, mutect2, varscan2
- NARF | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1272953041, COSV59112580; called by muse, mutect2, varscan2
- NLK | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV69409761; called by muse, mutect2, varscan2
- NME1-NME2 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.01); catalogued as rs866291175, COSV50147879; called by muse, mutect2, varscan2
- NPAS4 | c.1681T>C p.Y561H | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV60651363; called by muse, mutect2, varscan2
- NUP107 | c.822G>C p.E274D | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57495852; called by muse, mutect2, varscan2
- OR51F2 | c.705G>C p.E235D | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as rs768667172, COSV59065340, COSV59066280; called by muse, mutect2, varscan2
- OR51G1 | c.275G>C p.R92T | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs1453828638, COSV100429142, COSV58968441, COSV58969784; called by muse, mutect2, varscan2
- OR5B21 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64482079; called by muse, mutect2, varscan2
- OXR1 | c.1928C>T p.S643F (on ENST00000442977 / NM_001198532.1; = p.S642F on NM_018002.3) | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.646); catalogued as COSV100366658, COSV56328287; called by muse, mutect2, varscan2
- P3H2 | c.1094G>C p.R365T | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60024007; called by muse, mutect2, varscan2
- PAPSS1 | c.367G>C p.A123P | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54490521; called by muse, mutect2, varscan2
- PARP4 | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs113934879, COSV67962926; called by muse, mutect2, varscan2
- PDCL3 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV51809645; called by muse, mutect2, varscan2
- PER3 | c.3130C>A p.L1044M | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV62706637; called by muse, mutect2, varscan2
- PLA2G6 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 60/205 reads (29%) | catalogued as COSV100140358; called by muse, mutect2, varscan2
- PLA2R1 | c.2222G>C p.R741T | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1206713196, COSV51778384; called by muse, mutect2, varscan2
- PLA2R1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV51781928; called by muse, mutect2, varscan2
- PLB1 | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV59829844; called by muse, mutect2, varscan2
- PLCL1 | c.2576G>A p.R859H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1559099836, COSV70821454, COSV70821834; called by muse, mutect2, varscan2
- PLEKHH2 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV56756984; called by muse, mutect2
- PMS2 | c.809C>A p.S270* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | catalogued as COSV56223521, COSV99764141; called by muse, mutect2, varscan2
- PPP1R3A | c.1229C>G p.S410* | Nonsense Mutation (SNP) | VAF 86/176 reads (49%) | catalogued as COSV52880157, COSV99492660; called by muse, mutect2, varscan2
- PRRG4 | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); catalogued as rs147146504; called by muse, mutect2, varscan2
- PRUNE1 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54847814; called by muse, mutect2, varscan2
- PTGIR | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.842); catalogued as rs1248766058, COSV99354955; called by muse, mutect2, varscan2
- PTPRJ | c.940G>A p.V314M | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as rs777942402, COSV69253122; called by muse, mutect2, varscan2
- PTPRT | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs577588058, COSV61996457; called by muse, mutect2, varscan2
- RAPGEF4 | c.2803C>T p.H935Y | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99910410; called by muse, mutect2
- RAPGEF6 | c.2458G>C p.D820H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57249884; called by muse, mutect2, varscan2
- RFWD3 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.185); catalogued as COSV63098225; called by muse, mutect2, varscan2
- RIMS2 | c.3239C>G p.S1080W (on ENST00000666250 / NM_001348490.2; = p.S888W on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV51656632, COSV51697680; called by muse, mutect2, varscan2
- RSC1A1 | c.233C>G p.S78C | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); catalogued as COSV60780350; called by muse, mutect2, varscan2
- SCGB1D2 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.8); catalogued as rs775701487, COSV55274267; called by muse, mutect2, varscan2
- SCUBE1 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV51813522; called by muse, mutect2, varscan2
- SGSM2 | c.2170G>A p.D724N (on ENST00000426855 / NM_001098509.2; = p.D769N on NM_014853.3) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV52159472; called by muse, mutect2, varscan2
- SH2D4A | c.508A>G p.I170V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV56123445; called by muse, mutect2, varscan2
- SH3GL3 | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61058680; called by muse, varscan2
- SHOC1 | c.3439C>T p.Q1147* | Nonsense Mutation (SNP) | VAF 23/44 reads (52%) | catalogued as rs1487281815, COSV100597521; called by muse, mutect2, varscan2
- SLC17A6 | c.864G>C p.E288D | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV54138282; called by muse, mutect2, varscan2
- SLC6A6 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV62650851; called by muse, mutect2, varscan2
- SLC9A4 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs1329797133, COSV54836071; called by muse, mutect2, varscan2
- SLC9A6 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.227); catalogued as rs1556618832, COSV65787194, COSV65788420; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCA2 | c.4462A>T p.I1488F | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56647593; called by muse, mutect2, varscan2
- SMYD4 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as COSV59712197; called by muse, mutect2, varscan2
- SNRPN | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV57598505; called by muse, mutect2, varscan2
- SP7 | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs1409475721, COSV58191259; called by muse, mutect2, varscan2
- SYNDIG1L | c.624C>G p.F208L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV59046967, COSV59047937; called by muse, mutect2, varscan2
- SYT5 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV62829696; called by muse, mutect2, varscan2
- TANC1 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs1460073010, COSV55091360; called by muse, mutect2, varscan2
- TAOK1 | c.706C>T p.H236Y | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55594672; called by muse, mutect2
- TDP2 | c.1051C>T p.H351Y | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV61967891; called by muse, mutect2, varscan2
- TGFBR2 | c.1382del p.C461Lfs*7 | Frame Shift Del (DEL) | VAF 14/93 reads (15%) | catalogued as CM064338, COSV55453222; called by mutect2, pindel*, varscan2
- TIAM1 | c.1831C>T p.L611F | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99734528; called by muse, mutect2
- TMF1 | c.299T>A p.F100Y | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV68374866; called by muse, mutect2, varscan2
- TMPRSS4 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as rs536140913, COSV71108760; called by muse, mutect2, varscan2
- TSC2 | c.4693G>C p.E1565Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); catalogued as COSV51919911; called by muse, mutect2, varscan2
- TTC17 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV50011690; called by muse, mutect2, varscan2
- TTN | c.19568G>A p.G6523E (on ENST00000591111; = p.G5596E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | PolyPhen probably damaging (1); catalogued as COSV60172758; called by muse, mutect2, varscan2
- UBE2D1 | c.164A>G p.H55R | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV64218585; called by muse, mutect2, varscan2
- UBE2E2 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.02); catalogued as rs1480523422, COSV59973340; called by muse, mutect2, varscan2
- UTRN | c.2941G>C p.D981H | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV62340300; called by muse, mutect2, varscan2
- VAMP3 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); catalogued as COSV50012711; called by muse, mutect2, varscan2
- WAC | c.263_266del p.E88Gfs*103 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | catalogued as rs864321689; called by mutect2, pindel, varscan2
- WDR72 | c.2687G>A p.R896Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146417353, COSV64749794; called by muse, mutect2, varscan2
- XKR4 | c.1909G>A p.D637N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.617); catalogued as COSV59325793; called by muse, mutect2, varscan2
- ZAN | c.67C>G p.P23A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.942); catalogued as COSV61811412; called by muse, mutect2, varscan2
- ZBTB45 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs778279178, COSV63524530; called by muse, mutect2, varscan2
- ZFAND4 | c.2181C>G p.I727M | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1303054323, COSV60859815; called by muse, mutect2, varscan2
- ZMYND8 | c.2462C>G p.S821* (on ENST00000311275 / NM_001363741.2; = p.S841* on NM_012408.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/112 reads (21%) | catalogued as COSV99520176; called by muse, varscan2
- ZNF10 | c.767C>G p.S256* | Nonsense Mutation (SNP) | VAF 36/72 reads (50%) | catalogued as COSV99939944; called by muse, mutect2
- ZNF502 | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56074147; called by muse, mutect2, varscan2
- ZNF582 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV56732973; called by muse, mutect2, varscan2
- ZNF790 | c.1775C>T p.T592I | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV63212729; called by muse, mutect2, varscan2
- NPHP3 | c.3571G>A p.G1191R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- NSD1 | c.4882dup p.M1628Nfs*20 | Frame Shift Ins (INS) | VAF 23/38 reads (61%) | called by mutect2, pindel, varscan2
- POLE | c.4308_4310dup p.A1437dup | In Frame Ins (INS) | VAF 42/191 reads (22%) | called by mutect2, pindel, varscan2
- ABCF3 | c.6G>A p.A2= | Silent (SNP) | VAF 37/59 reads (63%) | catalogued as rs770539274, COSV53048989; called by muse, mutect2, varscan2
- ACLY | c.1200C>T p.I400= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV61251500; called by muse, mutect2, varscan2
- ADAM11 | c.423G>A p.G141= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as rs1163188741, COSV52345351; called by muse, mutect2, varscan2
- AKAP4 | c.150G>C p.L50= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV62074875; called by muse, mutect2
- AKAP6 | c.5481C>T p.G1827= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs1378906237, COSV55220809; called by muse, mutect2, varscan2
- ALMS1 | c.5349G>C p.L1783= | Silent (SNP) | VAF 59/179 reads (33%) | catalogued as COSV52508930, COSV52514137; called by muse, mutect2, varscan2
- ANO1 | c.1608C>T p.G536= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs771370159, COSV60286621; called by muse, mutect2, varscan2
- BIRC3 | c.897C>T p.L299= | Silent (SNP) | VAF 61/160 reads (38%) | catalogued as COSV54818142; called by muse, mutect2, varscan2
- C2orf73 | c.288C>T p.Y96= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs773328041, COSV58310563; called by muse, mutect2, varscan2
- CACNA1S | c.3381C>T p.L1127= | Silent (SNP) | VAF 70/166 reads (42%) | catalogued as rs749287388, COSV62941390; called by muse, mutect2, varscan2
- CCT4 | c.672G>A p.V224= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV66701669; called by muse, mutect2, varscan2
- CFAP77 | c.156C>A p.V52= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs1417599001, COSV100524655, COSV57504448; called by muse, mutect2, varscan2
- CHI3L2 | c.177C>T p.L59= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV63874340; called by muse, mutect2, varscan2
- COL6A3 | c.3279C>T p.N1093= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs777242754, COSV55094815; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CREB3L3 | c.192C>T p.L64= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs750591163, COSV50224309; called by muse, mutect2, varscan2
- CYP27A1 | c.507G>A p.A169= | Silent (SNP) | VAF 43/86 reads (50%) | catalogued as rs776260288, COSV51468575; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHX8 | c.2493C>A p.G831= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV99292156; called by muse, mutect2
- DNAJB12 | c.144C>T p.I48= (on ENST00000338820; = p.I14= on NM_017626.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV58760981, COSV58761270; called by muse, mutect2, varscan2
- DSTN | c.429C>T p.L143= | Silent (SNP) | VAF 52/89 reads (58%) | catalogued as COSV55713446; called by muse, mutect2, varscan2
- ENTPD4 | c.1782G>A p.R594= | Silent (SNP) | VAF 28/43 reads (65%) | catalogued as rs1281274169, COSV62268473; called by muse, mutect2, varscan2
- ERGIC2 | c.933C>T p.F311= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV64112652, COSV64113001; called by muse, mutect2, varscan2
- FAM91A1 | c.1956C>T p.L652= | Silent (SNP) | VAF 22/230 reads (10%) | catalogued as COSV58238065; called by muse, mutect2, varscan2
- FBN1 | c.4881G>A p.G1627= | Silent (SNP) | VAF 49/97 reads (51%) | catalogued as COSV57322469; called by muse, mutect2, varscan2
- FBN3 | c.6105C>G p.T2035= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV54465362; called by muse, mutect2, varscan2
- HTT | c.5781G>C p.L1927= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as COSV61864997, COSV61865531; called by muse, mutect2, varscan2
- ICA1L | c.390G>A p.L130= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV64173924; called by muse, mutect2, varscan2
- KCNS2 | c.759C>T p.L253= | Silent (SNP) | VAF 175/229 reads (76%) | catalogued as COSV54639520; called by muse, mutect2, varscan2
- KHDC4 | c.210C>T p.L70= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs770966396, COSV100850850, COSV64165281; called by muse, mutect2, varscan2
- KIAA0753 | c.2109A>G p.E703= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV63234770; called by muse, mutect2, varscan2
- KIRREL2 | c.1848C>T p.G616= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as rs1004093966, COSV52877850; called by muse, mutect2, varscan2
- KLC3 | c.660G>A p.Q220= | Silent (SNP) | VAF 15/20 reads (75%) | catalogued as rs1457210727, COSV67269063; called by muse, mutect2, varscan2
- MOCS1 | c.147C>T p.F49= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV57937705, COSV57938821; called by muse, mutect2, varscan2
- NLGN3 | c.1182C>T p.G394= (on ENST00000358741 / NM_181303.2; = p.G374= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV62443702, COSV62444244; called by muse, mutect2, varscan2
- NPAT | c.255A>G p.L85= | Silent (SNP) | VAF 41/102 reads (40%) | catalogued as rs139779135; called by muse, mutect2, varscan2
- OGFRL1 | c.492G>C p.L164= | Silent (SNP) | VAF 27/35 reads (77%) | catalogued as COSV64972180; called by muse, mutect2, varscan2
- PCDHA13 | c.1785C>T p.R595= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs782043806, COSV56521650; called by muse, mutect2, varscan2
- PDGFRA | c.1611T>C p.I537= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV57270431; called by muse, mutect2, varscan2
- POMC | c.711C>T p.Y237= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV53035215; called by muse, mutect2, varscan2
- RABGAP1L | c.24G>A p.Q8= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as rs779367893, COSV52307306; called by muse, mutect2, varscan2
- RANBP17 | c.3048C>T p.F1016= | Silent (SNP) | VAF 39/51 reads (76%) | catalogued as rs1254752961, COSV66653153; called by muse, mutect2, varscan2
- SH2B1 | c.1902G>A p.P634= (on ENST00000322610 / NM_001308293.1; = p.D668N on NM_015503.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs768714872, COSV59460173; called by muse, mutect2
- SHANK1 | c.3522C>A p.G1174= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV53255351; called by muse, mutect2, varscan2
- SLC35E3 | c.283C>T p.L95= | Silent (SNP) | VAF 50/102 reads (49%) | catalogued as rs372041461; called by muse, mutect2, varscan2
- SLC4A11 | c.2250C>T p.N750= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1467250264, COSV66262679; ClinVar: likely benign; called by muse, varscan2
- SP110 | c.1086G>A p.K362= | Silent (SNP) | VAF 39/138 reads (28%) | catalogued as COSV51257347; called by muse, mutect2, varscan2
- SV2C | c.1323C>T p.F441= | Silent (SNP) | VAF 32/44 reads (73%) | catalogued as COSV59223824; called by muse, mutect2, varscan2
- SYK | c.1617C>T p.Y539= | Silent (SNP) | VAF 24/134 reads (18%) | catalogued as rs201650753, COSV65325775, COSV65330072; called by muse, mutect2, varscan2
- TGM6 | c.972G>C p.L324= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV52481985; called by muse, mutect2, varscan2
- TMEM115 | c.534C>T p.L178= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs1375039624, COSV51705054; called by muse, mutect2, varscan2
- VIPR1 | c.1125C>T p.V375= | Silent (SNP) | VAF 86/187 reads (46%) | catalogued as rs927821279, COSV57297970; called by muse, mutect2, varscan2
- WDFY3 | c.9111G>A p.Q3037= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV55706481; called by muse, mutect2, varscan2
- ZBTB7A | c.156G>A p.L52= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as rs1483800801, COSV59327955; called by muse, mutect2, varscan2
- ARIH2 | c.-269C>T | 5'UTR (SNP) | VAF 9/18 reads (50%) | catalogued as rs1334541022, COSV62705363; called by muse, mutect2, varscan2
- BCCIP | chr10:125841330 G>A | 3'Flank (SNP) | VAF 28/52 reads (54%) | catalogued as COSV52941623; called by muse, varscan2
- CTBP2 | c.58+11962C>T | Intron (SNP) | VAF 36/83 reads (43%) | catalogued as rs1368606813, COSV58342825; called by muse, mutect2, varscan2
- PAX3 | chr2:222303977 G>C | 5'Flank (SNP) | VAF 6/18 reads (33%) | catalogued as rs1275579311, COSV54676138; called by muse, mutect2, varscan2
- POLDIP3 | c.*530G>A | 3'UTR (SNP) | VAF 15/19 reads (79%) | catalogued as COSV52809580; called by muse, mutect2, varscan2
